Surgical pathology report (de-identified scan), TCGA case TCGA-55-8096, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8096-01A (Primary Tumor).

SPECIMEN INFO

Collected:

Received:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Lateral section of left upper lobe, resection:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Histologic grade: Moderately differentiated.
3. Tumor site: Lateral segment left upper lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 3.8 x 2.8 x 2.5 cm.
6. Visceral pleural invasion: Yes.
7. Lymphovascular space invasion: No.

Surgical Margin Status:

1. Tumor distance from bronchial margin: Within 0.7 cm.
2. Tumor distance from parenchymal (stapled) margin: 0.7 cm.
3. Tumor distance from pleural surface: Tumor involves the pleura.

Other:

1. pTNM stage: T2.
- B. Level VI lymph node, excision:
Single lymph node, negative for malignancy (0/1).
- C. Level IX lymph node, excision:
Single lymph node, negative for malignancy (0/1).

Electronic Signature

COMMENTS:

Tissue will be submitted for lung cancer mutation studies; separate report to follow.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: female with left upper lobe lung nodule with history smoking and COPD

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Lateral segment of left upper lobe
- B. Level 6 lymph node
- C. Level 9 lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three formalin filled containers labeled with the patient's name

A. Additionally labeled lateral segment of left upper lobe and contains an 11.8 x 8.8 x 4.0 cm portion of lung surfaced by purple-gray anthracotic pleura and featuring two serpiginous staple lines 17.5 and 4.0 cm in greatest dimension. The pleura is remarkable for a 1.0 x 1.0 x 0.5 cm area of umbilication which is inked blue. The staple lines are removed and the underlying parenchyma is inked black. After removing the staple lines exposed segments of bronchi and vasculature are present and are grossly free of tumor. Sectioning reveals a 3.8 x 2.8 x 2.5 cm gray-white mass that abuts the pleura at the site of umbilication and approaches to within 0.7 cm of the inked parenchymal margin. The mass features a gray-white friable, soft cut surface. The remainder of the cut surface is beefy red and congested with areas of emphysematous change. Additional masses are not identified. Additionally, no discrete lymph nodes are identified. Representative sections are submitted in cassettes A1-8 labeled designated as follows: 1--exposed bronchial and vascular margins, en face; 2--inked deep margin closest to mass, perpendicular; 3-6-- mass to inked pleura, perpendicular; 7--

emphysematous change; 8--most normal appearing parenchyma. Additionally, a yellow green and blue cassette are submitted for Genomics research each labeled

B. Additionally labeled level 6 lymph node and contains two irregular black nodules consistent with anthracotic lymph nodes 1.0 cm, each. They are entirely submitted in cassette B labeled

C. Additionally labeled level 9 lymph node and contains a 1.0 cm purple-gray rubbery nodule bisected to reveal a black, anthracotic cut surface consistent with lymph node. The specimen is entirely submitted in cassette C labeled

Source: NCI Genomic Data Commons file 5895b469-9a60-42a3-92bd-404ea2b5f044 (TCGA-55-8096.D27900AE-8CF6-4D92-84E8-5247DF7D46B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).